Somatic mutation profile of tumor specimen 0DJHH9 from CCDI case PBBWIB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.2 years (7,011 days).
Specimen 0DJHH9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 194550c5-381c-429f-a3fc-3e7b9f4a8a2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJHDX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7e4d01a-bf9c-4a91-b07b-7290dcdc5be1

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HERC1 | c.13036C>G p.R4346G | Missense Mutation (SNP) | VAF 247/584 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV101497105; called by muse, mutect2, varscan2
- MMGT1 | c.185A>G p.H62R | Missense Mutation (SNP) | VAF 14/472 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.419); catalogued as rs879974522; called by muse, mutect2
- SETD2 | c.4920G>T p.W1640C | Missense Mutation (SNP) | VAF 138/391 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57439612, COSV57440632; called by muse, mutect2, varscan2
- IQCM | c.1135A>T p.I379F | Missense Mutation (SNP) | VAF 147/469 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- MYCBP2 | c.13250G>A p.C4417Y (on ENST00000357337; = p.C4455Y on NM_015057.5) | Missense Mutation (SNP) | VAF 13/355 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2
- TECPR1 | c.2557C>T p.L853= | Silent (SNP) | VAF 159/398 reads (40%) | catalogued as rs767853233, COSV65783179; called by muse, mutect2, varscan2
- WDPCP | c.873T>C p.F291= | Silent (SNP) | VAF 54/686 reads (8%) | called by muse, mutect2
- KIR3DL3 | c.*3C>T | 3'UTR (SNP) | VAF 192/801 reads (24%) | catalogued as rs770210827; called by muse, mutect2, varscan2
